Surgical pathology report (de-identified scan), TCGA case TCGA-FZ-5926, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-FZ-5926-01A (Primary Tumor).

PATIENT HISTORY:

The patient is [REDACTED] pancreatic adenocarcinoma associated with jaundice.

PRE OP DIAGNOSIS: Pancreatic cancer.

POST OP DIAGNOSIS: Same.

PROCEDURE: Laparoscopic Whipple.

SPECIMEN(S) RECEIVED:

- 1: LIVER BX
- 2: Gallbladder
- 3: CELIAC NODE
- 4: BILE DUCT
- 5: BILE DUCT
- 6: CYSTIC DUCT
- 7: Pancreas and Duodenum
- 8: NEW PANCREATIC MARGIN
- 9: Pyloric Margin & Omentum

ADDENDUM

Fluorescent in-situ hybridization studies have been performed on the moderately differentiated pancreatic adenocarcinoma. The ratio of HER2/neu gene to the centromere of chromosome 17 is 1.24 indicating a lack of amplification of HER2/neu gene in the targeted region.

FINAL DIAGNOSIS:

PART 1: LIVER, BIOPSY -

LIVER FRAGMENTS WITH MILD CHRONIC AND ACUTE INFLAMMATION OF THE PORTAL TRACTS, EDEMA AND BILE DUCT PROLIFERATION. NEGATIVE FOR TUMOR.

PART 2: GALLBLADDER, CHOLECYSTECTOMY -

CHRONIC CHOLECYSTITIS.

PART 3: TISSUE LABELLED "CELIAC LYMPH NODE", EXCISION -

PORTION OF PANCREAS WITH CHRONIC PANCREATITIS, FREE OF TUMOR. NO LYMPH NODE SEEN

PART 4: SEGMENT OF BILE DUCT, EXCISION -

METASTATIC ADENOCARCINOMA INVOLVING THE BILE DUCT MARGIN.

PART 5: SEGMENT OF BILE DUCT, REEXCISION -

CHRONIC INFLAMMATION. NO TUMOR SEEN.

PART 6: CYSTIC DUCT, EXCISION -

CHRONIC INFLAMMATION. NO TUMOR SEEN.

PART 7: PANCREAS AND DUODENUM, RESECTION (WHIPPLE'S PROCEDURE) -

A. INFILTRATING MODERATELY DIFFERENTIATED ADENOCARCINOMA (1.5 CM) EXTENDING TO PANCREATIC RESECTION MARGIN (#FS) AND INVADING PERIPANCREATIC ADIPOSE TISSUE AND THE MUSCULAR PROPRIA OF ADJACENT DUODENUM. FOCI OF ANGIOLYMPHATIC AND PERINEURAL INVASION IDENTIFIED.

B. FINAL SURGICAL RESECTION MARGINS, FREE OF TUMOR (SEE #8).

C. METASTATIC ADENOCARCINOMA IN EIGHT OUT OF EIGHTEEN LYMPH NODES, (8/18) WITH FOCAL EXTRACAPSULAR EXTENSION.

D. CHRONIC PANCREATITIS WITH FIBROSIS AND PROMINENCE OF ISLETS.

PART 8: NEW PANCREATIC MARGIN EXCISION -

PORTION OF PANCREAS WITH CHRONIC PANCREATITIS, FREE OF TUMOR.

PART 9: PYLORIC MARGIN AND OMENTUM, EXCISION -

A. GASTRIC PYLORIC WALL, FREE OF TUMOR.

B. OMENTUM WITH NO SIGNIFICANT PATHOLOGIC CHANGE.

SYNOPTIC- PRIMARY PANCREAS TUMORS

A. Type of resection: 1

1. Whipple
2. Partial pancreatectomy
3. Other

B. Tumor Type: 2

- | | |
|--------------------------------------|---|
| 1. Acinar cell | 9. Mucinous (colloid) carcinoma |
| 2. Adenocarcinoma | 10. Pancreaticoblastoma |
| 3. Adenosquamous | 11. Papillary carcinoma |
| 4. Carcinosarcoma | 12. Sarcoma (type #) |
| 5. Cystadenocarcinoma | 13. Small cell (oat cell) carcinoma |
| 6. Duct cell carcinoma | 14. Undifferentiated carcinoma |
| 7. Giant cell carcinoma | 15. Mucinous tumor of uncertain potential |
| 8. Islet cell (neuroendocrine) tumor | 16. Other |

C. History of Diabetes: N/A

1. Yes 2. No.

D. If the patient has a history of MEN, which one? N/A

1. MEN 1 2. MEN 2a 3. MEN 2b

E. Tumor size (maximum dimension): 1.5 cm.

F. Location: 1 1. Head 2. Body 3. Tail 4. Diffuse 5. Indeterminate

G. Resection Margins Free of Tumor: 1 1. Yes 2. No

H. Histologic grade of differentiation: 2 1. Well 2. Moderate 3. Poor 4. Indeterminate

I. Tumor Borders: 2 1. Pushing 2. Infiltrative

J. Vascular Invasion: 1 1. Yes 2. No 3. Unevaluable

K. Lymphatic Invasion: 1 1. Yes 2. No 3. Unevaluable

L. Perineural Invasion: 1 1. Yes 2. No 3. Unevaluable

M. Tumor extends into adjacent organs: 1 1. Yes 2. No

N. Mitoses per 10 HPF: 2-3

O. In situ carcinoma/dysplasia: 2 1. Yes. 2. No.

P. Non neoplastic pancreatic diseases: 1

1. Chronic pancreatitis
2. Pseudocyst.
3. Stones.

Q. Lymph nodes: 8 Positive/Total 18 of nodes = 8 / 18

R. Extracapsular invasion: 1 1. Yes. 2. No.

S. TNM Stage: T3 N1 Mx

Source: NCI Genomic Data Commons file 4ae5f1f7-33ba-455e-8d72-9be979e86e18 (TCGA-FZ-5926.D637640E-180F-4CBE-9F7D-2587E902DDA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).